Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LT-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Specimens Submitted:

- 1: SP: Anterior cul-de-sac
- 2: SP: Uterus, cervix, bilateral tubes and ovaries
- 3: SP: Left external iliac lymph nodes
- 4: SP: Left obturator lymph nodes
- 5: SP: Left hypogastric lymph nodes
- 6: SP: Left common iliac lymph nodes
- 7: SP: Right external iliac lymph nodes
- 8: SP: Right obturator lymph nodes
- 9: SP: Right hypogastric lymph nodes
- 10: SP: Left lateral external iliac lymph nodes

adenocarcinoma, endometrioid, NOS
8380/3
Site: Endometrium C54.1
lw
5/2/11

DIAGNOSIS:

- 1) CUL-DE-SAC, ANTERIOR, BIOPSY:
- FIBROUS TISSUE WITH CALCIFICATIONS AND FOCAL ENDOSALPINGIOSIS.
- 2-4,6-9) UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES; TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- TWO SEPARATE FOCI OF ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE WITH MUCINOUS FEATURES, FIGO GRADE II (6-50% SOLID GROWTH), NUCLEAR GRADE II.
- THE LARGER FOCUS OF TUMOR INVADERS $\leq$ HALF OF THE MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 3 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 8 MM.
- ENDOCERVICAL INVASION IS PRESENT BOTH IN THE MUCOSA AND THE STROMA.
- THE SMALLER FOCUS OF TUMOR IS LIMITED TO THE ENDOMETRIUM.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE MYOMETRIUM IS UNREMARKABLE.
- ALL ADNEXAE ARE UNREMARKABLE.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): RIGHT OBTURATOR: 0/1; RIGHT EXTERNAL ILIAC: 0/2; RIGHT HYPOGASTRIC: 0/7; LEFT OBTURATOR: 0/3; LEFT EXTERNAL ILIAC: 0/2; LEFT COMMON ILIAC: 0/1.

- 5) LYMPH NODES, LEFT HYPOGASTRIC, EXCISION:

** Continued on next page **

[page 2 of 2]
Page 2 of 6

- BENIGN FIBROADIPOSE TISSUE.
- NO LYMPH NODE IDENTIFIED IN ENTIRELY SUBMITTED SPECIMEN.

10) LYMPH NODES, LEFT LATERAL EXTERNAL ILIAC, EXCISION:

- BENIGN FIBROADIPOSE TISSUE.
- NO LYMPH NODE IDENTIFIED IN ENTIRELY SUBMITTED SPECIMEN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 8f171e8f-1ae2-4483-b8e8-5c1e6a5f1d96 (TCGA-AP-A0LT.4A25211C-354E-4FC8-B81B-29766B7962D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).